Somatic mutation profile of tumor specimen TCGA-A3-3311-01A (aliquot TCGA-A3-3311-01A-01D-0966-08) from TCGA case TCGA-A3-3311, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-A3-3311-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a320111-ff40-414d-899a-42391432ffd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3311-11A (Solid Tissue Normal), aliquot TCGA-A3-3311-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f1acbe1-d077-4dbc-ab63-758778f5f6e8

The open-access MAF lists 61 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 4, In Frame Del 3, Intron 1, Splice Region 1, Splice Site 1, 3'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG6 | c.2800G>T p.A934S | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51592040; called by muse, mutect2, varscan2
- ASIC4 | c.734C>G p.T245R | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61731758; called by muse, mutect2, varscan2
- ATP5F1A | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56360354; called by muse, mutect2, varscan2
- BRCA2 | c.6529A>G p.I2177V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV66453544; called by muse, mutect2, varscan2
- C4orf51 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV71264236; called by muse, mutect2, varscan2
- CAMK1D | c.586A>C p.K196Q | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV66611271; called by muse, mutect2, varscan2
- CCDC7 | c.3496A>C p.T1166P | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as COSV56541890; called by muse, mutect2
- CCKAR | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55161404, COSV55163388; called by muse, mutect2, varscan2
- CDK13 | c.2527A>T p.I843F | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51699691; called by muse, mutect2, varscan2
- CERCAM | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV65710929; called by muse, mutect2
- CERCAM | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV65710942; called by muse, mutect2
- CNNM3 | c.1224A>C p.R408= | Splice Region (SNP) | VAF 22/224 reads (10%) | catalogued as COSV59709167; called by muse, mutect2
- CSMD1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757822292, COSV68203443, COSV68254018, COSV68261658; called by muse, mutect2, varscan2
- CTDSPL2 | c.64A>T p.R22* | Nonsense Mutation (SNP) | VAF 49/193 reads (25%) | catalogued as COSV52946081; called by muse, mutect2, varscan2
- CYB5R1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs559078788, COSV61851518; called by muse, mutect2, varscan2
- ECT2 | c.935T>C p.V312A (on ENST00000392692 / NM_001349098.2; = p.V281A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV51688701; called by muse, mutect2, varscan2
- ELP3 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV56459079; called by muse, mutect2
- FANCI | c.2312T>C p.I771T | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV55526838; called by muse, mutect2, varscan2
- FBXL16 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60964470; called by muse, mutect2, varscan2
- FCRL4 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54862123; called by muse, mutect2, varscan2
- GOLPH3 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV54060752; called by muse, mutect2, varscan2
- INTS1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755337139, COSV67177413; called by muse, mutect2, varscan2
- JAML | c.968A>C p.K323T (on ENST00000356289 / NM_001098526.2; = p.K313T on NM_153206.3) | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV52627604; called by muse, mutect2, varscan2
- KIF21B | c.3698A>T p.D1233V | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV59757540; called by muse, mutect2, varscan2
- KLRC1 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61725209; called by muse, mutect2, varscan2
- MAP3K7 | c.1525-1G>T p.X509_splice (on ENST00000369329 / NM_145331.3; = p.X482_splice on NM_003188.4) | Splice Site (SNP) | VAF 19/79 reads (24%) | catalogued as COSV65224376; called by mutect2, varscan2
- MMEL1 | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV56521421, COSV56524299; called by muse, mutect2, varscan2
- OPTC | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs140125203; called by muse, mutect2, varscan2
- PBRM1 | c.3699T>G p.C1233W (on ENST00000296302 / NM_001366071.2; = p.C1208W on NM_018313.5) | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56275802; called by muse, mutect2, varscan2
- PGLYRP2 | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52993493; called by muse, mutect2, varscan2
- PROX1 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as COSV54778940; called by muse, mutect2, varscan2
- PTPRZ1 | c.4711G>A p.A1571T | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV66436248; called by muse, mutect2, varscan2
- SETD2 | c.7529G>A p.R2510H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV57430926, COSV57437405, COSV57449004; called by mutect2, varscan2
- SETMAR | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.052); catalogued as COSV62780777; called by muse, mutect2, varscan2
- TLR7 | c.2614C>T p.H872Y | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV66124272; called by muse, mutect2, varscan2
- TPTE2 | c.584G>C p.R195T (on ENST00000400230 / NM_199254.2; = p.R118T on NM_130785.3) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1268191005, COSV55020797; called by muse, mutect2, varscan2
- TUT7 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV52895617; called by muse, mutect2, varscan2
- WDR36 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs763068629, COSV72411162; called by muse, mutect2, varscan2
- WSCD1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs112285134, COSV58494358; called by muse, mutect2, varscan2
- ZMIZ2 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs763068838, COSV54807926; called by muse, mutect2, varscan2
- ZNF493 | c.1775A>G p.K592R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV62750018; called by muse, mutect2, varscan2
- CEP131 | c.2121_2124del p.V708Efs*10 (on ENST00000269392 / NM_001319228.2; = p.V705Efs*10 on NM_014984.4) | Frame Shift Del (DEL) | VAF 129/653 reads (20%) | called by mutect2, pindel, varscan2
- DHX57 | c.2101del p.A701Qfs*3 | Frame Shift Del (DEL) | VAF 49/189 reads (26%) | called by mutect2, pindel, varscan2
- EEA1 | c.2084del p.A695Efs*27 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- FGF2 | c.772del p.V258Wfs*3 | Frame Shift Del (DEL) | VAF 70/273 reads (26%) | called by mutect2, pindel, varscan2
- ITGB1 | c.2057_2062del p.D686_P687del | In Frame Del (DEL) | VAF 24/109 reads (22%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.2048_2065del p.H683_K688del | In Frame Del (DEL) | VAF 27/164 reads (16%) | called by mutect2, pindel, varscan2
- SULF1 | c.1215_1217del p.K405_I406delinsN | In Frame Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- C1orf158 | c.450G>A p.Q150= | Silent (SNP) | VAF 65/215 reads (30%) | catalogued as COSV55346721, COSV99847197; called by muse, mutect2, varscan2
- CARD9 | c.81C>G p.P27= | Silent (SNP) | VAF 93/231 reads (40%) | catalogued as COSV53733119; called by muse, mutect2, varscan2
- CDC42BPA | c.4392G>A p.V1464= (on ENST00000334218 / NM_001366019.2; = p.V1451= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV62010664; called by muse, mutect2, varscan2
- CPNE5 | c.810T>C p.S270= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV55196427; called by muse, mutect2, varscan2
- NICN1 | c.15G>A p.L5= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV56474593; called by muse, mutect2, varscan2
- PXDNL | c.1497G>T p.V499= | Silent (SNP) | VAF 76/332 reads (23%) | catalogued as COSV62487093; called by muse, mutect2, varscan2
- THAP9 | c.1788C>T p.V596= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV56356431; called by muse, mutect2, varscan2
- TRAPPC12 | c.222C>T p.D74= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV60847487; called by muse, mutect2, varscan2
- TRPV5 | c.369C>T p.I123= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as rs1305521296, COSV54685644; called by muse, mutect2, varscan2
- TTN | c.97251G>A p.R32417= (on ENST00000591111; = p.R24993= on NM_003319.4) | Silent (SNP) | VAF 65/228 reads (29%) | catalogued as rs1419519602, COSV59989941; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498559 C>G | 5'Flank (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- KDELR2 | c.*42G>C | 3'UTR (SNP) | VAF 82/292 reads (28%) | catalogued as rs771475262, COSV51726471, COSV51727355; called by muse, mutect2, varscan2
- PDE4B | c.635-67G>A | Intron (SNP) | VAF 34/115 reads (30%) | catalogued as rs200202611, COSV58464756; called by muse, mutect2, varscan2
